Somatic mutation profile of tumor specimen ALCH-AEG3-TTP1-A (aliquot ALCH-AEG3-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEG3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.8 years (24,036 days).
Specimen ALCH-AEG3-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a93d04dd-0c47-4ffb-94d1-683f8005c675.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEG3-NB1-A (Blood Derived Normal), aliquot ALCH-AEG3-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5d7f3de-796f-44ff-9dff-b2e756d08211

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Splice Site 3, 3'UTR 2, 5'UTR 1, In Frame Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 13/86 reads (15%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDC6 | c.1025A>C p.N342T | Missense Mutation (SNP) | VAF 27/401 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1202951063; called by muse, mutect2
- EDA2R | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 36/385 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs144036451, COSV53630319; called by muse, mutect2
- HMCN1 | c.8290+1G>A p.X2764_splice | Splice Site (SNP) | VAF 32/456 reads (7%) | catalogued as rs1351299207, COSV54931820; called by muse, mutect2
- IL12RB1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 42/477 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs150070244; ClinVar: uncertain significance; called by muse, mutect2
- OR13C8 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1262160225, COSV100622961; called by muse, mutect2, varscan2
- PHLDB2 | c.2271C>A p.N757K (on ENST00000393925 / NM_001134439.2; = p.N714K on NM_145753.2) | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs751833890; called by muse, mutect2, varscan2
- SYNGAP1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 36/1095 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1264547497, COSV99538004; called by muse, mutect2
- USP7 | c.2503A>G p.M835V | Missense Mutation (SNP) | VAF 33/495 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs757406176; called by muse, mutect2
- LARP4B | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- LZTR1 | c.1203C>A p.Y401* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.781C>A p.H261N | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- OR52E8 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2
- PNPLA4 | c.506C>G p.A169G | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF8 | c.6906A>C p.K2302N | Missense Mutation (SNP) | VAF 48/471 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- RNF212 | c.465-1G>A p.X155_splice | Splice Site (SNP) | VAF 12/227 reads (5%) | called by muse, mutect2
- SDHAF2 | c.256_260+1del p.X86_splice | Splice Site (DEL) | VAF 34/354 reads (10%) | called by mutect2, pindel
- SLC4A2 | c.3081G>T p.Q1027H | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SLC6A13 | c.1214T>A p.M405K | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SPTLC2 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 78/842 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- SREBF1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMD | c.2223G>T p.V741= | Silent (SNP) | VAF 62/526 reads (12%) | called by muse, mutect2, varscan2
- HOXA10 | c.201C>T p.P67= | Silent (SNP) | VAF 44/239 reads (18%) | called by muse, mutect2, varscan2
- IZUMO1 | c.282G>A p.L94= | Silent (SNP) | VAF 31/376 reads (8%) | called by muse, mutect2
- KIAA2026 | c.5724C>T p.S1908= | Silent (SNP) | VAF 45/296 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.12303C>T p.G4101= | Silent (SNP) | VAF 23/194 reads (12%) | catalogued as rs772443215, COSV67480603; called by muse, mutect2, varscan2
- NAA38 | c.270C>G p.S90= (on ENST00000575771 / NM_001320925.2; = p.S138= on NM_032356.5) | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- ZNF395 | c.129C>T p.P43= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs267601890; called by muse, varscan2
- ZSWIM6 | c.3204C>A p.A1068= | Silent (SNP) | VAF 44/242 reads (18%) | called by muse, mutect2, varscan2
- MAN2B1 | c.1026+29G>A | Intron (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- MNX1 | c.-30G>A | 5'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2795G>A | 3'UTR (SNP) | VAF 57/462 reads (12%) | called by muse, mutect2, varscan2
- ZNF99 | c.*2816T>C | 3'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as COSV68056225; called by muse, mutect2, varscan2
